EXCEPTIONAL_RESPONDERS case ER-ABXQ — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dde8b69b-d22f-4d79-8238-65af41db0134

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive.

Diagnoses (1)
1. Merkel cell carcinoma: ICD-O-3 morphology code: 8247/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 67.8 years (24,753 days); Year of diagnosis: 2009; AJCC staging edition: 7th; AJCC pathologic stage: Stage IA; Prior malignancy: no; Days to last follow up: 2,122 days (5.8 years); Days to best overall response: 1,112 days (3.0 years); Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Topotecan; Days to treatment start: 1,056 days (2.9 years); Days to treatment end: 2,225 days (6.1 years).

Follow-up (1 entry)
- Days to follow up: 2,122 days (5.8 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,039 days (2.8 years); Days progression-free: 2,122 days (5.8 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABXQ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-ABXQ-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
